Somatic mutation profile of tumor specimen TCGA-CR-6487-01A (aliquot TCGA-CR-6487-01A-11D-1870-08) from TCGA case TCGA-CR-6487, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tonsil, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 50.2 years (18,331 days).
Specimen TCGA-CR-6487-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6aba0615-7ddc-47db-bc3a-14188307ebdf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CR-6487-10A (Blood Derived Normal), aliquot TCGA-CR-6487-10A-01D-1870-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0b263579-05f0-4fc7-9321-ef3213367632

The open-access MAF lists 131 somatic variants for this specimen: 104 protein-altering or splice-affecting, 25 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 86, Silent 25, Nonsense Mutation 14, Splice Site 1, 5'UTR 1, Nonstop Mutation 1, Frame Shift Del 1, In Frame Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 80/223 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCC3 | c.2338G>A p.A780T | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1213242201, COSV99559308; called by muse, mutect2, varscan2
- ADAM12 | c.2299C>T p.H767Y | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV64115373; called by muse, mutect2
- ADAM32 | c.814G>A p.D272N | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV101165420; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.7453C>T p.Q2485* | Nonsense Mutation (SNP) | VAF 23/110 reads (21%) | catalogued as COSV99783626; called by muse, mutect2, varscan2
- APBB1 | c.335G>A p.G112D | Missense Mutation (SNP) | VAF 49/249 reads (20%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.461); catalogued as COSV100194124; called by muse, mutect2, varscan2
- ARMC10 | c.1005G>T p.K335N | Missense Mutation (SNP) | VAF 28/344 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs750973183, COSV100085741; called by muse, mutect2
- ATP13A4 | c.2123C>G p.S708* | Nonsense Mutation (SNP) | VAF 13/217 reads (6%) | catalogued as rs1019114647, COSV100710434; called by muse, mutect2
- AXL | c.2570C>T p.A857V (on ENST00000301178 / NM_021913.5; = p.A848V on NM_001699.6) | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.671); catalogued as rs61737385, COSV56574640; called by muse, mutect2, varscan2
- C9orf135 | c.665C>T p.T222I | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as rs1156885024, COSV101019885; called by muse, mutect2, varscan2
- CEP55 | c.818A>T p.Q273L | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.078); catalogued as COSV101017077; called by muse, mutect2, varscan2
- COL6A3 | c.4604G>A p.R1535H | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs115765346, COSV55084955; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPS1 | c.1232C>T p.P411L | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.167); catalogued as rs769284353, COSV51821680, COSV99243226; called by muse, mutect2, varscan2
- CSMD3 | c.1495G>A p.G499R (on ENST00000297405 / NM_001363185.1; = p.G395R on NM_052900.3) | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778693042, COSV52188195; called by muse, mutect2, varscan2
- CTNNA1 | c.398C>G p.S133C | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV100242952; called by muse, mutect2, varscan2
- DENND3 | c.1696G>A p.V566I | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs759205642, COSV52804648; called by muse, mutect2
- EHMT1 | c.1567C>T p.R523W | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs562496442, COSV100603970; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EP300 | c.1567C>T p.Q523* | Nonsense Mutation (SNP) | VAF 15/69 reads (22%) | catalogued as COSV99608888; called by muse, mutect2, varscan2
- EXOSC10 | c.479C>T p.A160V | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.034); catalogued as COSV100442614; called by muse, mutect2, varscan2
- FAM193A | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); catalogued as rs774212724, COSV100219293; called by muse, mutect2, varscan2
- FARS2 | c.428A>G p.N143S | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.66); catalogued as COSV99213045; called by muse, varscan2
- FLG2 | c.15G>C p.L5F | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101165934, COSV66166729; called by muse, mutect2, varscan2
- GPR162 | c.230G>A p.R77H | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.093); catalogued as rs1457517841, COSV99163696; called by muse, mutect2, varscan2
- GRIA1 | c.2117G>A p.R706Q | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99597914; called by muse, mutect2, varscan2
- IRF2BP1 | c.449C>T p.A150V | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.165); catalogued as COSV100138910; called by muse, mutect2, varscan2
- ISYNA1 | c.988G>A p.V330M | Missense Mutation (SNP) | VAF 45/228 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs769634970, COSV54210147; called by muse, mutect2, varscan2
- ITPRID1 | c.2876A>G p.Q959R | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.49); catalogued as COSV100086640; called by muse, mutect2
- KCNK13 | c.782A>G p.N261S | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1280344767, COSV99965756; called by muse, mutect2, varscan2
- KIR3DL3 | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 91/265 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.063); catalogued as rs367886097; called by muse, mutect2, varscan2
- KLK3 | c.288C>A p.F96L | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.32); catalogued as COSV100386022, COSV58100576; called by muse, mutect2, varscan2
- KMT2D | c.4895C>G p.S1632* | Nonsense Mutation (SNP) | VAF 17/84 reads (20%) | catalogued as CD114126, COSV104396507, COSV99982885; called by muse, mutect2, varscan2
- KMT2D | c.166C>T p.Q56* | Nonsense Mutation (SNP) | VAF 43/201 reads (21%) | catalogued as COSV56441661; called by muse, mutect2, varscan2
- LDHD | c.1315G>A p.E439K | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as rs748756112, COSV100097186; called by muse, mutect2, varscan2
- LHX4 | c.616C>T p.Q206* | Nonsense Mutation (SNP) | VAF 28/156 reads (18%) | catalogued as rs761101623, COSV99761643; called by muse, mutect2, varscan2
- LMO4 | c.355C>T p.R119W | Missense Mutation (SNP) | VAF 33/160 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.975); catalogued as rs1356595620, COSV65170668; called by muse, mutect2, varscan2
- LRFN2 | c.1462G>A p.D488N | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.692); catalogued as rs55706368, COSV100599630; called by mutect2, varscan2
- LTN1 | c.5159C>T p.S1720L | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100798029; called by muse, mutect2, varscan2
- MAK | c.1688A>G p.H563R | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.066); catalogued as COSV100504465; called by muse, mutect2, varscan2
- MAP2 | c.2992C>A p.Q998K | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.089); catalogued as COSV99560434; called by muse, mutect2, varscan2
- MC2R | c.802A>T p.N268Y | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV100563051; called by muse, mutect2, varscan2
- MFN1 | c.233T>C p.V78A | Missense Mutation (SNP) | VAF 76/488 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54940289; called by muse, mutect2, varscan2
- MFN2 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.212); catalogued as rs754016178, COSV99336825; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MLEC | c.106G>A p.V36M | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.099); catalogued as rs1184411173, COSV99949681; called by muse, varscan2
- MLN | c.68C>T p.T23M | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as rs746105078, COSV99803045; called by muse, mutect2, varscan2
- MMP13 | c.1285G>A p.D429N | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as rs1354598556, COSV99506614; called by muse, mutect2, varscan2
- MMP16 | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs760497058, COSV54161518, COSV99688817; called by muse, mutect2, varscan2
- MYO1E | c.2579G>A p.R860H | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.047); catalogued as rs767509482, COSV99895807; called by muse, mutect2, varscan2
- MYO3B | c.77C>T p.T26I | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.836); catalogued as rs941857271, COSV100510543; called by muse, mutect2, varscan2
- NAV3 | c.3562C>T p.R1188C | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs1263381855, COSV57076949, COSV57096164; called by muse, mutect2, varscan2
- NBAS | c.5434G>C p.E1812Q | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.07); catalogued as COSV99870231; called by muse, mutect2, varscan2
- NIPSNAP1 | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV99331175; called by muse, mutect2, varscan2
- NISCH | c.1921G>A p.E641K | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.083); catalogued as COSV100617408; called by muse, mutect2, varscan2
- NLRP4 | c.298C>G p.Q100E | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.696); catalogued as COSV56719687; called by muse, mutect2, varscan2
- NPHP4 | c.2897G>T p.S966I | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.098); catalogued as COSV100976971; called by muse, mutect2, varscan2
- NRF1 | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.935); catalogued as rs764173748, COSV56210750; called by muse, mutect2, varscan2
- NUP210L | c.3136G>C p.E1046Q | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as COSV99055498, COSV99668287; called by muse, mutect2, varscan2
- OR1J4 | c.760A>G p.T254A | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.075); catalogued as COSV100534290; called by muse, mutect2, varscan2
- OR51V1 | c.512A>T p.Y171F | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.999); catalogued as COSV100343400; called by muse, mutect2, varscan2
- OR5D16 | c.406G>A p.V136I | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.319); catalogued as COSV101004000; called by muse, mutect2, varscan2
- PARP11 | c.479C>T p.T160M | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV57395509; called by muse, mutect2, varscan2
- PCCA | c.739C>G p.Q247E | Missense Mutation (SNP) | VAF 34/190 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.021); catalogued as COSV66190373; called by muse, varscan2
- PCDH1 | c.557T>G p.L186R | Missense Mutation (SNP) | VAF 55/283 reads (19%) | SIFT tolerated (0.89); PolyPhen possibly damaging (0.897); catalogued as COSV99746400; called by muse, mutect2, varscan2
- PCDHGA1 | c.674C>T p.T225I | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.461); catalogued as COSV100965998; called by muse, mutect2, varscan2
- PCDHGA9 | c.94C>T p.R32C | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.967); catalogued as COSV53959341; called by muse, mutect2, varscan2
- PCNX1 | c.3403C>T p.Q1135* | Nonsense Mutation (SNP) | VAF 17/97 reads (18%) | catalogued as COSV99455963; called by muse, mutect2, varscan2
- PEG3 | c.1023C>G p.F341L | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.74); PolyPhen benign (0.005); catalogued as COSV55629429, COSV99689286; called by muse, mutect2, varscan2
- PIK3CB | c.1701G>C p.E567D | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.02); catalogued as COSV100005756, COSV56691757; called by muse, mutect2, varscan2
- PKHD1L1 | c.4824A>T p.E1608D | Missense Mutation (SNP) | VAF 90/315 reads (29%) | SIFT tolerated (0.48); PolyPhen benign (0.262); catalogued as COSV101006295; called by muse, mutect2, varscan2
- PLCB1 | c.2270T>C p.I757T | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.249); catalogued as rs1488351224, COSV100571320; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLEKHG4 | c.1700C>T p.T567M | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs368565515; called by muse, mutect2, varscan2
- PLPPR4 | c.1322C>T p.S441F | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV100926668, COSV100926963; called by muse, mutect2, varscan2
- POC5 | c.1159G>C p.E387Q (on ENST00000428202 / NM_001099271.2; = p.E362Q on NM_152408.2) | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as COSV100994378; called by muse, mutect2, varscan2
- POLL | c.1702C>T p.R568* | Nonsense Mutation (SNP) | VAF 14/64 reads (22%) | catalogued as rs540905898, COSV100150323, COSV100150392; called by muse, mutect2, varscan2
- POLR3A | c.2398G>T p.G800* | Nonsense Mutation (SNP) | VAF 9/69 reads (13%) | catalogued as COSV100965685; called by muse, mutect2, varscan2
- PRDM15 | c.3400G>T p.E1134* | Nonsense Mutation (SNP) | VAF 14/75 reads (19%) | catalogued as COSV99520269; called by muse, mutect2, varscan2
- PSMA6 | c.706G>C p.D236H | Missense Mutation (SNP) | VAF 32/178 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV99809209; called by muse, varscan2
- RGS3 | c.3018G>T p.M1006I (on ENST00000350696 / NM_001282923.2; = p.M725I on NM_130795.4) | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100636786; called by muse, mutect2, varscan2
- RPP40 | c.549G>A p.W183* | Nonsense Mutation (SNP) | VAF 5/32 reads (16%) | catalogued as COSV100124015; called by muse, mutect2, varscan2
- RXRG | c.158C>G p.P53R | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.327); catalogued as COSV100717610; called by muse, mutect2, varscan2
- SERPINI1 | c.1177C>T p.R393* | Nonsense Mutation (SNP) | VAF 54/718 reads (8%) | catalogued as rs761133163, CM138046, COSV55508793; called by muse, mutect2
- SI | c.2587A>G p.T863A | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV100015887; called by muse, mutect2
- SLC44A1 | c.1973G>C p.*658Sext*2 | Nonstop Mutation (SNP) | VAF 37/216 reads (17%) | catalogued as COSV100570492; called by muse, mutect2, varscan2
- SLC66A2 | c.648C>G p.F216L | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.29); catalogued as COSV100301897, COSV100302153; called by muse, mutect2, varscan2
- SLF2 | c.1072G>C p.E358Q | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV53275986; called by muse, mutect2, varscan2
- SMAD1 | c.776-1G>A p.X259_splice | Splice Site (SNP) | VAF 44/157 reads (28%) | catalogued as COSV100129787, COSV57472668, COSV57472877; called by muse, mutect2, varscan2
- SMARCD1 | c.344C>T p.A115V | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs376164103; called by muse, mutect2, varscan2
- SRRM2 | c.5653C>T p.R1885* | Nonsense Mutation (SNP) | VAF 9/66 reads (14%) | catalogued as rs1180028514, COSV100070970; called by muse, mutect2, varscan2
- TEX55 | c.286G>A p.D96N | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV99817586; called by muse, mutect2, varscan2
- THUMPD2 | c.1399G>C p.D467H | Missense Mutation (SNP) | VAF 29/183 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV99572207; called by muse, mutect2, varscan2
- TMIGD3 | c.419C>T p.T140I (on ENST00000369717 / NM_001081976.2; = p.T221I on NM_020683.7) | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100778410; called by muse, mutect2, varscan2
- TOR4A | c.889G>A p.V297M | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV62627016; called by muse, mutect2
- TTN | c.12622G>A p.E4208K (on ENST00000591111; = p.E4162K on NM_003319.4) | Missense Mutation (SNP) | VAF 30/132 reads (23%) | catalogued as rs920878697, COSV60420081; called by muse, mutect2, varscan2
- UBE2Q1 | c.740C>G p.S247C | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.093); catalogued as COSV99427511; called by muse, mutect2, varscan2
- USH1C | c.437C>T p.T146I | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated (0.79); PolyPhen possibly damaging (0.47); catalogued as COSV99140319; called by muse, mutect2, varscan2
- VSX2 | c.680G>A p.R227Q | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1198436631, COSV100001664; called by muse, mutect2, varscan2
- WDR44 | c.701C>T p.A234V | Missense Mutation (SNP) | VAF 82/158 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.164); catalogued as COSV99561630; called by muse, mutect2, varscan2
- XRN1 | c.1256A>G p.E419G | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV99378196; called by muse, mutect2, varscan2
- ZBTB11 | c.2780G>T p.R927L | Missense Mutation (SNP) | VAF 29/151 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.645); catalogued as COSV100465537, COSV57244782; called by muse, mutect2, varscan2
- ZFYVE26 | c.3022C>T p.R1008* | Nonsense Mutation (SNP) | VAF 8/29 reads (28%) | catalogued as rs766888372, COSV100720493; called by muse, mutect2, varscan2
- ZNF320 | c.1345G>A p.A449T | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.194); catalogued as COSV101206876; called by muse, mutect2
- ZNF324B | c.1451C>T p.T484M | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); catalogued as rs762582025, COSV60741475; called by muse, mutect2, varscan2
- ARHGAP20 | c.2768del p.L923Yfs*5 | Frame Shift Del (DEL) | VAF 24/117 reads (21%) | called by mutect2, pindel, varscan2
- HEATR9 | c.675G>C p.E225D | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- TDG | c.126_127insCTTCAA p.E42_E43insLQ | In Frame Ins (INS) | VAF 9/49 reads (18%) | called by mutect2, pindel, varscan2
- ABCA4 | c.3540G>A p.S1180= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs767212006, COSV100933062; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAM10 | c.1155T>C p.V385= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as COSV53055168; called by muse, varscan2
- AIFM1 | c.912G>A p.T304= | Silent (SNP) | VAF 59/97 reads (61%) | catalogued as rs907702631, COSV99780698, COSV99781254; called by muse, mutect2, varscan2
- ATG2B | c.3126C>T p.D1042= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as COSV100738073; called by muse, mutect2, varscan2
- BDH1 | c.423C>T p.L141= | Silent (SNP) | VAF 14/272 reads (5%) | catalogued as rs773545278, COSV100827154; called by muse, mutect2
- BICDL1 | c.1197C>T p.D399= | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as rs1298393061, COSV57494395; called by muse, mutect2, varscan2
- CCT6B | c.21C>G p.V7= | Silent (SNP) | VAF 6/59 reads (10%) | catalogued as COSV100030719; called by muse, mutect2, varscan2
- DIAPH1 | c.3657T>C p.R1219= | Silent (SNP) | VAF 15/86 reads (17%) | catalogued as COSV99526711; called by muse, mutect2, varscan2
- DSCAM | c.912G>A p.V304= | Silent (SNP) | VAF 31/205 reads (15%) | catalogued as COSV101260452; called by muse, mutect2, varscan2
- GJB5 | c.270C>T p.L90= | Silent (SNP) | VAF 21/101 reads (21%) | catalogued as rs780478774, COSV58356231; called by muse, mutect2, varscan2
- KCTD8 | c.723C>T p.I241= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs1316891381, COSV63585841, COSV63593698; called by muse, mutect2, varscan2
- MAN1A2 | c.894C>G p.L298= | Silent (SNP) | VAF 15/132 reads (11%) | catalogued as COSV100740959; called by muse, mutect2, varscan2
- OBSCN | c.10332C>T p.T3444= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as rs371792687; called by muse, mutect2, varscan2
- OR5L2 | c.127C>T p.L43= | Silent (SNP) | VAF 68/325 reads (21%) | catalogued as COSV65725463; called by muse, mutect2, varscan2
- OR6M1 | c.678C>T p.P226= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV58433352; called by muse, mutect2, varscan2
- PIK3C2A | c.3012C>A p.I1004= | Silent (SNP) | VAF 30/164 reads (18%) | catalogued as COSV99790865; called by muse, mutect2, varscan2
- POLR3D | c.735C>T p.L245= | Silent (SNP) | VAF 4/47 reads (9%) | catalogued as rs984121548, COSV100120123; called by muse, mutect2
- RP1 | c.6150T>C p.N2050= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV99607768; called by muse, mutect2
- RREB1 | c.1437G>A p.S479= | Silent (SNP) | VAF 28/254 reads (11%) | catalogued as rs760414247, COSV100619437; called by muse, mutect2, varscan2
- SMC1A | c.2556C>T p.L852= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as COSV100447461; called by muse, mutect2, varscan2
- STK36 | c.2454C>T p.D818= | Silent (SNP) | VAF 21/120 reads (18%) | catalogued as COSV99831528; called by muse, mutect2, varscan2
- TDP1 | c.633C>T p.L211= | Silent (SNP) | VAF 22/122 reads (18%) | catalogued as rs991871187, COSV100187885; called by muse, mutect2, varscan2
- TEX2 | c.2778G>A p.L926= (on ENST00000583097 / NM_001288733.2; = p.L933= on NM_018469.5) | Silent (SNP) | VAF 55/285 reads (19%) | catalogued as COSV99367181; called by muse, mutect2, varscan2
- TMEM50B | c.450T>C p.F150= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as COSV101336646; called by muse, mutect2, varscan2
- VMO1 | c.399C>T p.L133= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV99564714; called by muse, mutect2, varscan2
- ATP7A | c.-21-8989C>G | Intron (SNP) | VAF 5/30 reads (17%) | catalogued as COSV100431018; called by muse, mutect2, varscan2
- PCDHA1 | c.-1A>G | 5'UTR (SNP) | VAF 35/208 reads (17%) | catalogued as COSV100974380; called by muse, mutect2, varscan2
